FM case AD1585 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/a50e57a5-0f85-4c3c-8068-944bda4a037a

Male, 49.3 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
